Somatic mutation profile of tumor specimen 0DK843 from CCDI case PBBWUR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.1 years (2,585 days).
Specimen 0DK843: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2a66af6-2f8b-4bdd-8648-f4bfb9ee5c64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK83S (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0674aa5a-4766-4888-93d3-000244e1df60

The open-access MAF lists 14 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Nonsense Mutation 3, Intron 3, 5'UTR 2, RNA 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 188/233 reads (81%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- CAPN9 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 37/711 reads (5%) | catalogued as rs1443273037; called by muse, mutect2
- CTAGE1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 202/255 reads (79%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs576826595; called by muse, mutect2, varscan2
- ITGA8 | c.1762C>T p.R588* | Nonsense Mutation (SNP) | VAF 127/332 reads (38%) | catalogued as rs1358323528, COSV65237036; called by muse, mutect2, varscan2
- NDST3 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs775212321, COSV56628137, COSV56632105; called by muse, mutect2, varscan2
- TDO2 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 23/637 reads (4%) | catalogued as rs530115805; called by muse, mutect2
- WDR17 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 304/347 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54568753, COSV54570582; called by muse, mutect2, varscan2
- MKKS | c.861C>T p.H287= | Silent (SNP) | VAF 32/380 reads (8%) | catalogued as rs1329682768; called by muse, mutect2
- CEP43 | c.301-89T>C | Intron (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- ELMO1 | c.243+25T>C | Intron (SNP) | VAF 166/480 reads (35%) | called by muse, mutect2, varscan2
- KAT6A | c.1903-89T>G | Intron (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 9/146 reads (6%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 7/56 reads (13%) | called by muse, varscan2
- VN1R1 | c.-48C>A | 5'UTR (SNP) | VAF 18/245 reads (7%) | called by muse, mutect2
